Somatic mutation profile of tumor specimen TCGA-5M-AAT4-01A (aliquot TCGA-5M-AAT4-01A-11D-A40P-10) from TCGA case TCGA-5M-AAT4, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.2 years (27,095 days).
Specimen TCGA-5M-AAT4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d5a19f7-0556-4a4e-969b-b1a81b603d01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5M-AAT4-10A (Blood Derived Normal), aliquot TCGA-5M-AAT4-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf45f15b-b115-4310-a85e-82a5bf285f98

The open-access MAF lists 191 somatic variants for this specimen: 150 protein-altering or splice-affecting, 35 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 35, Nonsense Mutation 7, Frame Shift Del 6, Frame Shift Ins 4, Intron 2, RNA 2, 3'UTR 1, In Frame Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 69/186 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 34/143 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/159 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAGI2 | c.1808T>G p.L603R | Missense Mutation (SNP) | VAF 63/152 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62636665, COSV62664406; called by muse, mutect2, varscan2
- PCBP1 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 55/146 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57850093, COSV57850258, COSV57850830; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 66/94 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748717715, COSV62788907, COSV62790498; called by muse, mutect2
- AC098582.1 | c.536C>G p.A179G | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV99985676; called by muse, mutect2, varscan2
- AC126283.2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773085612, CM161603, COSV67098504; called by muse, mutect2, varscan2
- ACOX3 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV100711954; called by muse, mutect2, varscan2
- ACOX3 | c.547T>G p.F183V | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100711966; called by muse, mutect2, varscan2
- ADAM18 | c.458T>C p.L153S | Missense Mutation (SNP) | VAF 275/439 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV99695683; called by muse, mutect2, varscan2
- AGTPBP1 | c.2213C>G p.S738* (on ENST00000357081 / NM_001330701.2; = p.S698* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 15/189 reads (8%) | catalogued as COSV100429868; called by muse, mutect2
- AKAP11 | c.4586G>T p.G1529V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV99214011; called by muse, mutect2, varscan2
- AKAP6 | c.6923A>C p.N2308T | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV99801515; called by muse, mutect2
- ALK | c.4091A>C p.Q1364P | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101202161; called by muse, mutect2
- ANKRD44 | c.1759C>A p.L587M | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.378); catalogued as COSV56560041, COSV99985197; called by muse, mutect2
- APC | c.4455del p.D1486Ifs*21 | Frame Shift Del (DEL) | VAF 84/157 reads (54%) | catalogued as COSV57321956; called by mutect2, pindel, varscan2
- APOE | c.685G>C p.G229R | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as rs1299844242, COSV99376152; called by muse, mutect2, varscan2
- ASCC2 | c.801C>A p.C267* | Nonsense Mutation (SNP) | VAF 11/125 reads (9%) | catalogued as COSV100316311; called by muse, mutect2
- ATF6B | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.401); catalogued as rs372075542; called by muse, mutect2, varscan2
- ATP11C | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100558070; called by muse, mutect2
- ATP9B | c.2987C>T p.P996L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1304072135, COSV100303068, COSV100304112; called by muse, mutect2, varscan2
- B4GALT4 | c.730T>C p.F244L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100785816; called by muse, mutect2
- B4GALT4 | c.728T>G p.F243C | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100785818; called by muse, mutect2
- BRINP3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.147); catalogued as rs375567534, COSV66538726; called by muse, mutect2, varscan2
- C2CD3 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100486872; called by muse, varscan2
- C9orf72 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.281); catalogued as COSV101186527; called by muse, mutect2, varscan2
- CACNA1E | c.5701C>T p.R1901C | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs199591744, COSV62394080; called by muse, varscan2
- CDH20 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.271); catalogued as rs528882646, COSV53008475; called by muse, mutect2, varscan2
- CDHR5 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.382); catalogued as rs1350269268, COSV51564731; called by muse, mutect2, varscan2
- CDHR5 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1211824413, COSV51564686; called by muse, varscan2
- CHL1 | c.2807G>T p.W936L (on ENST00000397491 / NM_001253387.1; = p.W952L on NM_006614.4) | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99851456; called by muse, mutect2, varscan2
- CLDN8 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as rs893943148, COSV54525776; called by muse, mutect2, varscan2
- CNTNAP5 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70472881, COSV70490958; called by muse, mutect2, varscan2
- CSMD1 | c.7580A>C p.K2527T (on ENST00000520002; = p.K2526T on NM_033225.6) | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100149210; called by muse, mutect2, varscan2
- CTSK | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV55011554, COSV55012182; called by muse, mutect2
- CXorf66 | c.580C>A p.L194I | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.275); catalogued as COSV100983903; called by muse, mutect2
- CYP27C1 | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV100079881; called by muse, mutect2, varscan2
- DGKB | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1273697325, COSV99340298; called by muse, mutect2, varscan2
- DNALI1 | c.297G>T p.E99D (on ENST00000296218; = p.E77D on NM_003462.5) | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as COSV99953634; called by muse, mutect2, varscan2
- DOK1 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV99284100; called by muse, mutect2, varscan2
- DST | c.9339G>T p.E3113D | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV99757181; called by muse, mutect2, varscan2
- EIF4B | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 217/429 reads (51%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.248); catalogued as COSV100016840; called by muse, mutect2, varscan2
- EPHA5 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.226); catalogued as COSV99899409; called by muse, mutect2, varscan2
- FAM111A | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100659373; called by muse, mutect2, varscan2
- FAM83B | c.2201C>G p.T734S | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100174571, COSV60924539; called by muse, mutect2, varscan2
- FMNL3 | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV99526445; called by muse, mutect2, varscan2
- FN1 | c.5885G>T p.G1962V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100117317; called by muse, mutect2, varscan2
- FOXN2 | c.1112C>G p.P371R | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV100489269; called by muse, mutect2, varscan2
- GAB2 | c.1139G>T p.R380I (on ENST00000361507 / NM_080491.3; = p.R342I on NM_012296.3) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as COSV100416554; called by muse, mutect2, varscan2
- GATAD2A | c.1575+1G>C p.X525_splice | Splice Site (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99390298; called by muse, mutect2, varscan2
- GFRA4 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs768661396, COSV99293924; called by muse, mutect2, varscan2
- GLIPR1L2 | c.32G>C p.W11S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV100157860; called by muse, mutect2, varscan2
- GORAB | c.758G>T p.C253F | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV100883835; called by muse, mutect2
- GRIA2 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.869); catalogued as COSV52392635; called by muse, mutect2, varscan2
- GRIN2A | c.3347A>C p.K1116T | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV58023969, COSV58048538; called by muse, mutect2, varscan2
- H4C2 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55138254, COSV99774715, COSV99774982; called by muse, mutect2
- IFI6 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100191495; called by muse, mutect2, varscan2
- IL18RAP | c.87dup p.L30Tfs*10 | Frame Shift Ins (INS) | VAF 106/362 reads (29%) | catalogued as rs756319084; called by mutect2, pindel*, varscan2
- ITGA7 | c.1246C>T p.R416W (on ENST00000555728; = p.R372W on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752464052, COSV99146046; called by muse, mutect2, varscan2
- ITSN1 | c.5048C>T p.A1683V | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs777159341, COSV101182069; called by muse, mutect2
- JRK | c.495C>G p.F165L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV101401110, COSV70630528; called by muse, mutect2
- KCNAB3 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745768999, COSV100376045; called by muse, mutect2, varscan2
- KCNJ15 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765815153, COSV60811301; called by muse, mutect2, varscan2
- KDR | c.3164A>C p.K1055T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99817930; called by muse, mutect2, varscan2
- KIAA1109 | c.2948C>T p.P983L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs774896445, COSV99165333; called by muse, mutect2, varscan2
- KIF7 | c.2563G>T p.E855* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101067736; called by muse, mutect2, varscan2
- KMT2A | c.5621C>T p.A1874V | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.166); catalogued as rs782094920, COSV100629035; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT27 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.015); catalogued as rs749080763, COSV100053284; called by muse, mutect2
- LGALS4 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100313261; called by muse, mutect2, varscan2
- MAGI2 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs760517354, COSV62654789; called by muse, mutect2
- MARCHF4 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1214830803, COSV56102656; called by muse, mutect2, varscan2
- MBD1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs897086935; called by muse, mutect2
- MCF2 | c.1070A>G p.E357G | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100644834, COSV104407467; called by muse, mutect2
- MGAM | c.2988C>A p.C996* | Nonsense Mutation (SNP) | VAF 39/184 reads (21%) | catalogued as COSV101527535; called by muse, mutect2, varscan2
- MGAT3 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1376292335, COSV57864043; called by muse, mutect2, varscan2
- MIA3 | c.1068G>C p.Q356H | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV100719468, COSV60512421; called by muse, mutect2
- MMP26 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV56171303; called by muse, mutect2
- MSH5 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as rs1269438723, COSV100994901; called by muse, mutect2
- NCOA7 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV99997221, COSV99997459; called by muse, mutect2, varscan2
- NEUROG2 | c.558C>G p.F186L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100511875; called by muse, mutect2
- NPAS3 | c.1858G>A p.A620T (on ENST00000356141 / NM_001164749.2; = p.A588T on NM_022123.3) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs763025424, COSV60821859; called by muse, mutect2, varscan2
- NPFFR1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV99524859; called by muse, mutect2
- NPHP4 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs766910538, COSV100976970; called by muse, mutect2, varscan2
- NYX | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 119/141 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs745419686, COSV100699428; called by muse, mutect2, varscan2
- ODAM | c.122T>G p.L41R | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101258057; called by muse, mutect2
- OPRM1 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs779965433, COSV57677841; called by muse, mutect2, varscan2
- OR2M5 | c.842T>G p.L281R | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100822831; called by muse, mutect2
- OR5T2 | c.904A>C p.S302R | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs867798059, COSV57588098; called by muse, mutect2
- OR6Y1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778242664, COSV100225401; called by muse, mutect2, varscan2
- OR7G2 | c.430T>G p.Y144D | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100560466; called by muse, mutect2, varscan2
- OTOA | c.566G>C p.G189A | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.027); catalogued as COSV99624801; called by muse, mutect2, varscan2
- PAK3 | c.591A>T p.E197D (on ENST00000262836 / NM_001324328.2; = p.E182D on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 554/654 reads (85%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs764106735, COSV53273699; called by mutect2, varscan2
- PAK5 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV100781393; called by muse, mutect2, varscan2
- PARD3 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as rs12570964, COSV100400753, COSV60745413, COSV60751463; called by muse, mutect2, varscan2
- PCDHB8 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs782064898, COSV99177056; called by muse, mutect2, varscan2
- PKD1 | c.2774G>A p.R925Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs759227115, COSV99238300; called by muse, mutect2, varscan2
- PLA2G4E | c.1921T>A p.S641T | Missense Mutation (SNP) | VAF 95/139 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68153104; called by muse, mutect2, varscan2
- PLXND1 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV100139910; called by muse, mutect2, varscan2
- PML | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332038475, COSV99167362; called by muse, mutect2, varscan2
- POR | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs72557929, CM087162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRLHR | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV53304613, COSV99492835; called by muse, mutect2, varscan2
- PSMB4 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.469); catalogued as rs546112706, COSV51850201; called by muse, mutect2, varscan2
- PTCHD3 | c.2270C>G p.S757C | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV101438914; called by muse, mutect2
- PTGER3 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV100139073; called by muse, mutect2
- RBM27 | c.1960G>C p.A654P | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99506247; called by muse, mutect2, varscan2
- RFTN1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 72/111 reads (65%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs368097786, COSV100489878; called by muse, mutect2, varscan2
- RNF213 | c.7052A>T p.Y2351F | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV100300764; called by muse, mutect2, varscan2
- SERPINB5 | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 106/177 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV101237659; called by muse, mutect2, varscan2
- SOS2 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV53566002, COSV99366256; called by muse, mutect2
- SOX11 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV100431193; called by muse, mutect2
- SPACA4 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as rs368363901, COSV99614097; called by muse, mutect2, varscan2
- SQLE | c.459G>C p.E153D | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1429307885, COSV99772383; called by muse, mutect2
- SRCAP | c.5321C>T p.S1774L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as rs769850314, COSV99350337; called by muse, mutect2, varscan2
- STMN3 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100899868; called by muse, mutect2, varscan2
- SV2C | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV100456335; called by muse, mutect2, varscan2
- TAF4 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.274); catalogued as rs767666911, COSV53340922; called by muse, mutect2
- TBC1D10A | c.1357C>A p.Q453K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV99304696; called by muse, mutect2, varscan2
- TIMP4 | c.633C>A p.H211Q | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99826038; called by muse, mutect2, varscan2
- TMEM45A | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100058430; called by muse, mutect2, varscan2
- TMEM63C | c.1933C>G p.P645A | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100029484, COSV53606407; called by muse, mutect2, varscan2
- TNFAIP3 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99396857; called by muse, mutect2, varscan2
- TRIM27 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV101019352; called by muse, mutect2
- TRIM42 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.022); catalogued as rs746925342, COSV99648437; called by muse, mutect2
- TRIM46 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs747314139, COSV58116170; called by muse, mutect2, varscan2
- U2AF2 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.969); catalogued as rs111455063, COSV100454289; called by muse, varscan2
- UBR1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.88); PolyPhen benign (0.411); catalogued as COSV99317357; called by muse, mutect2, varscan2
- USH2A | c.2348A>C p.N783T | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV56327866, COSV56347503; called by muse, mutect2, varscan2
- USP20 | c.2654A>C p.E885A | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100204397; called by muse, mutect2, varscan2
- VIRMA | c.2408C>T p.T803I | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as COSV99888587; called by muse, mutect2, varscan2
- XKR5 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.316); catalogued as COSV101306692; called by muse, mutect2, varscan2
- XPO6 | c.947T>A p.I316N | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100485093; called by muse, mutect2, varscan2
- ZBTB16 | c.1816C>G p.L606V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100251617; called by muse, mutect2
- ZBTB4 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 104/147 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as COSV100263215, COSV100263435; called by muse, mutect2, varscan2
- ZDHHC11 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 56/359 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as rs371035335; called by muse, mutect2, varscan2
- ZNF214 | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 103/175 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV53484248; called by muse, mutect2, varscan2
- ZNF227 | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV100480442; called by muse, mutect2, varscan2
- ZNF492 | c.244A>T p.R82* | Nonsense Mutation (SNP) | VAF 126/284 reads (44%) | catalogued as COSV101514008, COSV71761956; called by muse, mutect2, varscan2
- ZNF875 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs552933332, COSV100183357; called by muse, mutect2
- CAVIN4 | c.348dup p.V117Sfs*2 | Frame Shift Ins (INS) | VAF 124/385 reads (32%) | called by mutect2, pindel, varscan2
- FBXW7 | c.909_912dup p.A305Sfs*13 (on ENST00000281708 / NM_001349798.2; = p.A225Sfs*13 on NM_018315.5) | Frame Shift Ins (INS) | VAF 63/187 reads (34%) | called by mutect2, pindel, varscan2
- INSRR | c.1136_1137del p.T379Rfs*91 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- MAP2K4 | c.1037del p.L346Cfs*17 | Frame Shift Del (DEL) | VAF 46/94 reads (49%) | called by mutect2, pindel, varscan2
- MPP6 | c.415del p.E139Nfs*5 | Frame Shift Del (DEL) | VAF 55/172 reads (32%) | called by mutect2, pindel, varscan2
- PPP1R1B | c.290_293del p.N97Rfs*45 | Frame Shift Del (DEL) | VAF 32/71 reads (45%) | called by mutect2, pindel, varscan2
- STAG2 | c.3623del p.T1208Kfs*3 | Frame Shift Del (DEL) | VAF 209/322 reads (65%) | called by mutect2, pindel, varscan2
- TBX3 | c.408dup p.K137* | Frame Shift Ins (INS) | VAF 20/153 reads (13%) | called by mutect2, pindel, varscan2
- TSPAN10 | c.189_191dup p.P64dup (on ENST00000574882 / NM_001290212.1; = p.P26dup on NM_031945.4) | In Frame Ins (INS) | VAF 24/53 reads (45%) | called by mutect2, pindel, varscan2
- ZNF488 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AL645922.1 | c.246G>A p.A82= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as rs754668308, COSV54959283; called by muse, mutect2, varscan2
- ANKRD10 | c.648G>A p.L216= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as COSV99941153; called by muse, mutect2, varscan2
- ANO3 | c.609C>T p.P203= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as rs778253031, COSV99883362; called by muse, mutect2, varscan2
- AP2A2 | c.2331C>T p.T777= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as rs554369040, COSV100173040; called by muse, mutect2, varscan2
- ATE1 | c.933C>G p.T311= | Silent (SNP) | VAF 58/179 reads (32%) | catalogued as COSV56438404, COSV99816748, COSV99817287; called by muse, mutect2, varscan2
- BARD1 | c.1638A>T p.P546= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99638874; called by muse, mutect2, varscan2
- CAD | c.3549A>G p.K1183= | Silent (SNP) | VAF 135/364 reads (37%) | catalogued as COSV99255192; called by muse, mutect2, varscan2
- CHD9 | c.3831T>C p.D1277= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99529258; called by muse, mutect2
- CNGA2 | c.846C>A p.I282= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV100323603, COSV100323745, COSV61705645; called by muse, mutect2
- COL14A1 | c.780C>A p.S260= | Silent (SNP) | VAF 8/208 reads (4%) | catalogued as COSV99919528; called by muse, mutect2
- CPPED1 | c.81C>T p.S27= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs566259758, COSV99903263; called by muse, mutect2
- ETNK2 | c.358C>T p.L120= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV99689576; called by muse, mutect2, varscan2
- GRIA2 | c.1710C>T p.Y570= | Silent (SNP) | VAF 55/212 reads (26%) | catalogued as rs538981621, COSV52380934, COSV99642409; called by muse, mutect2, varscan2
- GRIA4 | c.1683C>A p.V561= | Silent (SNP) | VAF 9/184 reads (5%) | catalogued as COSV99232111; called by muse, mutect2
- HEPH | c.2523G>T p.V841= (on ENST00000343002; = p.V574= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/86 reads (80%) | catalogued as COSV100295007; called by muse, mutect2, varscan2
- INTS9 | c.1536G>A p.R512= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV101273893; called by muse, mutect2
- KCNA5 | c.399G>A p.T133= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as rs752249172, COSV99363940; called by muse, mutect2, varscan2
- KLC2 | c.384C>G p.A128= | Silent (SNP) | VAF 67/141 reads (48%) | catalogued as COSV100385116; called by muse, mutect2, varscan2
- OR13A1 | c.108G>A p.S36= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as COSV100980974, COSV65573108, COSV65573571; called by muse, mutect2
- PCDHA1 | c.714C>T p.N238= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as rs782103349, COSV65373257; called by muse, mutect2, varscan2
- PCDHB11 | c.1272C>T p.T424= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV100697033; called by muse, varscan2
- PLXNA1 | c.3795C>T p.I1265= | Silent (SNP) | VAF 39/68 reads (57%) | catalogued as rs769380903, COSV99303291; called by muse, mutect2, varscan2
- PPARGC1A | c.957T>A p.S319= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV99338041; called by muse, mutect2, varscan2
- PRLHR | c.114G>A p.S38= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs759397071, COSV99492837; called by muse, mutect2, varscan2
- RBMXL2 | c.798C>T p.R266= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as rs1473265924, COSV100182292; called by muse, mutect2
- RNF43 | c.573C>T p.P191= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV68459139; called by muse, mutect2, varscan2
- SHROOM2 | c.4626C>T p.H1542= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as COSV101098747; called by muse, mutect2, varscan2
- STK19 | c.789C>A p.T263= (on ENST00000375333 / NM_032454.1; = p.T259= on NM_004197.1) | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV100941719; called by muse, mutect2, varscan2
- STRA8 | c.684C>T p.G228= (on ENST00000275764; = p.G206= on NM_182489.2) | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1202145593, COSV99312477; called by muse, mutect2, varscan2
- TNFSF15 | c.606C>T p.C202= | Silent (SNP) | VAF 57/189 reads (30%) | catalogued as rs184980312, COSV100928302; called by muse, mutect2, varscan2
- TRPA1 | c.1641C>T p.D547= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs752559794, COSV100083351; called by muse, mutect2, varscan2
- TTC8 | c.999A>G p.E333= (on ENST00000338104 / NM_001288781.1; = p.E317= on NM_144596.4) | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as COSV100581406; called by muse, mutect2, varscan2
- VCAN | c.9291G>A p.P3097= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as rs375652154; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- XPO6 | c.1710C>T p.Y570= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV100485092; called by muse, mutect2, varscan2
- ZNF423 | c.1149C>T p.S383= (on ENST00000563137 / NM_001379286.1; = p.S375= on NM_015069.4) | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs375403632, COSV52195156; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD300LD | c.40+61G>A | Intron (SNP) | VAF 42/84 reads (50%) | catalogued as rs201588570, COSV60085004; called by muse, mutect2
- CDH8 | c.*2A>G | 3'UTR (SNP) | VAF 50/133 reads (38%) | catalogued as rs1567403669, COSV100182087; called by muse, mutect2, varscan2
- KNOP1P1 | n.355C>T | RNA (SNP) | VAF 8/181 reads (4%) | called by muse, mutect2
- PKD1L2 | n.279G>A | RNA (SNP) | VAF 22/77 reads (29%) | catalogued as rs760002031; called by muse, mutect2, varscan2
- RPL10 | chrX:154403317 G>A | 3'Flank (SNP) | VAF 5/88 reads (6%) | catalogued as rs782524223, COSV50010565; called by muse, mutect2
- TTN | c.10361-4555A>C | Intron (SNP) | VAF 12/138 reads (9%) | catalogued as COSV100617138, COSV100636014; called by muse, mutect2
